Somatic mutation profile of tumor specimen 0E0UHZ from CCDI case PBCVMN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0UHZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fac3ead-34a2-40a2-9058-003913ae1aec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0UI5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e24e001-b160-4fb2-83e6-365808053458

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Frame Shift Ins 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.5211-1G>A p.X1737_splice | Splice Site (SNP) | VAF 185/547 reads (34%) | catalogued as CS126676, COSV71108890; called by muse, mutect2, varscan2
- FBXW7 | c.1598G>A p.C533Y (on ENST00000281708 / NM_001349798.2; = p.C453Y on NM_018315.5) | Missense Mutation (SNP) | VAF 233/440 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55924459; called by muse, mutect2, varscan2
- SHANK2 | c.1594G>A p.V532I | Missense Mutation (SNP) | VAF 277/834 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs533451110, COSV53602890; called by muse, mutect2, varscan2
- TMEM129 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 155/441 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1055782415; called by muse, mutect2, varscan2
- WDR91 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 34/724 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs747135607, COSV60368797; called by muse, mutect2
- LRRC45 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 26/712 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- TMEM53 | c.426dup p.D143* | Frame Shift Ins (INS) | VAF 195/712 reads (27%) | called by mutect2, pindel, varscan2
- ZIC5 | c.1784T>C p.V595A | Missense Mutation (SNP) | VAF 134/409 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MGAM | c.5556G>A p.T1852= | Silent (SNP) | VAF 208/524 reads (40%) | catalogued as rs562639920, COSV72074478, COSV72074611; called by muse, mutect2, varscan2
- OIT3 | c.57C>T p.P19= | Silent (SNP) | VAF 61/418 reads (15%) | catalogued as rs1490914710; called by muse, mutect2, varscan2
- OR13C8 | c.606G>A p.S202= | Silent (SNP) | VAF 202/455 reads (44%) | catalogued as rs146773946; called by muse, mutect2, varscan2
- FIG4 | c.1039+24A>G | Intron (SNP) | VAF 12/287 reads (4%) | called by muse, mutect2
